Gene-level copy-number profile of tumor specimen TCGA-R6-A6Y0-01B from TCGA case TCGA-R6-A6Y0, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G2; Age at diagnosis: 54.9 years (20,045 days).
Specimen TCGA-R6-A6Y0-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.91e45a2e-1a90-4f0d-a266-ee27777c4ce7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R6-A6Y0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/5ab9ca80-adc0-412e-84ae-9805657a9cc5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 9,165; copy number 2: 23,113; copy number 3: 16,170; copy number 4: 8,125; copy number 5: 1,579; copy number 6: 1,148; copy number 7: 194; copy number 8: 153; copy number 9: 57; copy number 10: 24; copy number 12: 14; copy number 28: 9; copy number 43: 20.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.
- chr17:66,302,613–66,810,743, 1 gene (within-gene range 0–5): PRKCA.
- chr17:66,398,069–66,787,168, 5 genes: PRKCA-AS1, RNU6-928P, RNA5SP445, AC006947.1, MIR634.
- chr17:72,627,231–73,092,712, 6 genes (within-gene range 0–3): RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1.
- chr20:15,280,764–15,619,819, 3 genes: RNA5SP475, AL121584.1, ENSAP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,198 genes in 81 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,472,288–11,102,100, 16 genes, copy number 5–9 (within-gene range 2–9): PEX14, AL139423.2, RN7SL614P, CASZ1, AL139423.1, HSPE1P24, C1orf127, CFL1P6, TARDBP, AL109811.3, MASP2, AL109811.2, SRM, EXOSC10, AL109811.1, EXOSC10-AS1.
- chr1:11,907,940–12,512,047, 22 genes, copy number 5 (within-gene range 3–5): AL021155.4, RNU5E-1, RNU5E-4P, KIAA2013, PLOD1, AL096840.2, MFN2, AL096840.1, MIIP, Y_RNA, MIR6729, RN7SL649P, TNFRSF8, RNU6-777P, RPL23AP89, AL357835.1, MIR7846, TNFRSF1B, MIR4632, RPL10P17, SNORA70, VPS13D.
- chr1:15,756,607–16,161,883, 22 genes, copy number 6: FBLIM1, RPL12P14, UQCRHL, AL450998.1, FLJ37453, SPEN, AL034555.1, ZBTB17, AL355994.4, AL355994.1, AL355994.5, TBC1D3P6, SRARP, AL355994.3, HSPB7, CLCNKA, AL355994.2, CLCNKB, FAM131C, EPHA2, AL451042.2, AL451042.1.
- chr1:151,557,446–152,196,699, 39 genes, copy number 9: AL365436.1, SNX27, AL391335.1, RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2, AL450992.3, KRT8P28, S100A10, AL450992.1, NBPF18P, S100A11, SPTLC1P4, AL591893.1, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN.
- chr1:160,670,778–161,118,055, 24 genes, copy number 5 (within-gene range 3–5): AL121985.1, CD48, SLAMF7, AL121985.3, AL121985.2, LY9, CD244, PPIAP37, ITLN1, AL354714.2, AL354714.3, AL354714.1, AL354714.4, ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2.
- chr1:166,895,711–171,444,963, 109 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr1:172,138,397–173,352,004, 21 genes, copy number 7: DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1, TNFSF18, GOT2P2, AL022310.1, TNFSF4, AL645568.2.
- chr1:234,535,963–235,074,220, 21 genes, copy number 5–9: AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348.
- chr2:97,618,638–99,490,035, 38 genes, copy number 5–7: AC017099.2, UBTFL6, COX5B, ACTR1B, C2orf92, RNU4-8P, ZAP70, TMEM131, HMGN1P36, RNU7-96P, VWA3B, ATP5F1BP1, AC092675.1, CNGA3, AC092675.2, INPP4A, COA5, UNC50, MGAT4A, YWHAQP5, LINC02611, RNU4-84P, CRACDL, RNU7-46P, TSGA10, SMC3P1, AC079447.1, C2orf15, LIPT1, AC092587.1, MITD1, MRPL30, LYG2, LYG1, TXNDC9, EIF5B, REV1, AC018690.1.
- chr2:190,189,735–191,425,389, 24 genes, copy number 8 (within-gene range 4–8): HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P.
- chr2:205,681,990–206,420,238, 27 genes, copy number 5: NRP2, AC007362.1, RN7SKP178, PPIAP68, AC007679.1, INO80D, Vault, Y_RNA, RPL27P8, AC007383.1, NDUFS1, AC007383.2, GCSHP3, EEF1B2, AC007383.3, snoZ196, SNORD51, SNORA41, GPR1, GPR1-AS, RN7SKP200, ATP5POP1, HMGN1P6, RN7SKP260, ZDBF2, ACER2P1, HNRNPA1P51.
- chr3:108,380,368–109,410,084, 24 genes, copy number 5 (within-gene range 3–5): MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2, DZIP3, AC092185.1, RETNLB, TRAT1, GUCA1C, MORC1, U3, MORC1-AS1, C3orf85, AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12.
- chr6:729,128–1,613,897, 18 genes, copy number 5–7: AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1.
- chr6:43,450,352–43,852,333, 23 genes, copy number 10: DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1.
- chr7:876,554–1,621,405, 28 genes, copy number 7: GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2.
- chr7:9,082,557–24,537,438, 186 genes, copy number 5–6 (broad region; genes not listed).
- chr7:27,128,969–27,662,883, 41 genes, copy number 6 (within-gene range 3–6): AC004080.6, HOXA-AS3, HOXA5, HOXA6, AC004080.5, HOXA7, AC004080.4, HOXA9, AC004080.3, HOXA10-AS, MIR196B, HOXA10, HOXA11, HOXA11-AS, AC004080.7, AC004080.14, AC004080.8, AC004080.2, AC004080.12, AC004080.15, AC004080.13, HOXA13, HOTTIP, AC004080.9, AC004080.16, AC004080.10, AC004080.11, AC004080.17, AC004080.1, EVX1-AS, EVX1, RPL35P4, HNRNPA1P73, AC004009.1, AC004009.3, AC004009.2, EIF4HP1, PSMC1P2, AC073150.1, HIBADH, AC007130.1.
- chr8:37,405,439–40,520,158, 86 genes, copy number 5–6 (broad region; genes not listed).
- chr8:49,536,386–145,066,685, 1,467 genes, copy number 5–8 (broad region; genes not listed).
- chr10:74,151,202–75,236,030, 22 genes, copy number 5 (within-gene range 2–5): ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1.
- chr11:75,099,172–75,669,120, 23 genes, copy number 5 (within-gene range 3–5): AP001972.4, SLCO2B1, OR2AT1P, AP001972.3, ZDHHC20P3, TPBGL, ARRB1, AP001972.1, AP001972.5, AP001972.2, MIR326, RPS3, SNORD15A, SNORD15B, KLHL35, GDPD5, AP002815.1, SERPINH1, AP001922.5, MAP6, AP001922.6, AP001922.2, AP001922.4.
- chr11:76,759,916–81,556,425, 69 genes, copy number 5–6 (broad region; genes not listed).
- chr11:102,396,332–103,092,194, 24 genes, copy number 5 (within-gene range 4–5): TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2.
- chr12:6,924,463–7,240,986, 27 genes, copy number 5: ATN1, C12orf57, U47924.2, RNU7-1, PTPN6, MIR200CHG, MIR200C, MIR141, U47924.1, PHB2, SCARNA12, EMG1, LPCAT3, C1S, AC006512.1, AC006512.2, C1R, C1RL, C1RL-AS1, RBP5, RNU6-485P, AC018653.3, CLSTN3, AC018653.4, AC018653.1, PEX5, AC018653.2.
- chr12:12,049,844–13,982,002, 53 genes, copy number 5: BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1, AC092824.1, CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1, APOLD1, MIR613, STX8P1, DDX47, AC007215.1, AC007688.2, RPL13AP20, GPRC5A, MIR614, GPRC5D-AS1, GPRC5D, AC007688.3, AC007688.1, HEBP1, HTR7P1, AC023790.2, AC023790.1, FAM234B, GSG1, EMP1, AC022276.1, LINC01559, GRIN2B, RNA5SP353, RNU6-590P, AC007527.1, AC007527.2, AC007535.1, RN7SKP162.
- chr12:31,111,652–31,993,107, 38 genes, copy number 5 (within-gene range 4–5): AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1.
- chr14:20,556,093–20,875,768, 21 genes, copy number 7: RNASE9, AL163195.3, RNASE11, AL163195.2, RNASE12, AL163195.1, OR6S1, Y_RNA, ANG, RNASE4, AL163636.1, EGILA, RANBP20P, EDDM3DP, EDDM3A, EDDM3B, RNASE6, AL133371.2, RNASE1, AL133371.3, AL133371.1.
- chr14:31,025,106–31,861,224, 19 genes, copy number 6 (within-gene range 3–6): AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P.
- chr14:102,922,663–103,345,025, 21 genes, copy number 8 (within-gene range 4–8): AMN, CDC42BPB, AL117209.1, RPL13P6, LBHD2, AL161669.1, EXOC3L4, AL161669.4, LINC00677, TNFAIP2, NDUFB4P11, RPL21P12, GCSHP2, LINC00605, AL161669.2, AL161669.3, RPL21P13, RAP2CP1, AL138976.1, AL138976.2, EIF5.
- chr14:104,677,694–105,398,147, 33 genes, copy number 8 (within-gene range 4–8): MIR4710, INF2, AL583722.3, ADSS1, SIVA1, AL583722.1, AKT1, ZBTB42, AL590326.1, LINC00638, RPS26P49, RPS2P4, AL583810.2, AL583810.1, CEP170B, AL583810.3, PLD4, AHNAK2, CLBA1, CDCA4, GPR132, LINC02298, AL512356.4, AL512356.3, AL512356.2, AL512356.5, JAG2, MIR6765, AL512356.1, NUDT14, BRF1, BTBD6, PACS2.
- chr16:3,953,387–4,690,974, 31 genes, copy number 5 (within-gene range 2–5): ADCY9, AC005736.1, AC009171.1, AC009171.2, SRL, LINC01569, TFAP4, GLIS2, GLIS2-AS1, PAM16, AC012676.1, CORO7-PAM16, AC012676.5, CORO7, VASN, DNAJA3, AC012676.3, AC012676.4, AC012676.2, NMRAL1, HMOX2, CDIP1, AC023830.3, C16orf96, AC023830.2, SUB1P3, UBALD1, MGRN1, RN7SL850P, AC023830.1, Metazoa_SRP.
- chr17:38,671,703–39,564,907, 49 genes, copy number 6 (within-gene range 3–6): EPOP, MIR4734, AC006449.6, AC006449.2, MLLT6, AC006449.3, MIR4726, AC006449.7, CISD3, RNA5SP440, PCGF2, AC006449.5, PSMB3, RNU6-866P, PIP4K2B, CWC25, MIR4727, C17orf98, RPL23, SNORA21B, SNORA21, AC110749.1, LASP1, AC006441.1, MIR6779, AC006441.3, LINC00672, FBXO47, AC006441.2, AC006441.4, AC006441.5, LINC02079, LRRC37A11P, AC091178.1, RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P.
- chr17:75,394,123–75,905,093, 29 genes, copy number 7: AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1, H3-3B, MIR4738, UNK, AC087289.1, UNC13D, WBP2, TRIM47, AC087289.5, TRIM65, AC087289.2, MRPL38.
- chr18:2,948,238–4,455,307, 32 genes, copy number 5 (within-gene range 3–5): AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66.
- chr18:9,102,630–9,960,021, 32 genes, copy number 6 (within-gene range 4–6): NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3, AP005432.2, RALBP1, AP005432.1, RNU2-27P, PPP4R1, AP001381.1, PPP4R1-AS1, RNU6-903P, LINC02856, KRT18P8, RAB31, AP000902.1, ZNF415P1, RN7SL862P, AC006238.2, RNA5SP449, PIGPP4, TXNDC2, AC006238.1, VAPA, RNA5SP450.
- chr18:21,817,624–22,419,294, 21 genes, copy number 5: SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1.
- chr19:867,630–1,174,268, 20 genes, copy number 6 (within-gene range 2–6): MED16, RNU6-9, R3HDM4, KISS1R, ARID3A, AC005379.1, AC005391.1, WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2.
- chr19:28,790,812–30,228,715, 37 genes, copy number 8–43: MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr20:62,143,769–63,505,111, 76 genes, copy number 6 (broad region; genes not listed).
- chr22:33,922,422–36,703,752, 62 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,848. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
